FM case AD13559 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/431d2829-71e8-4dbf-979f-43c7ae913ba7

Male, 78.2 years: Non-small cell carcinoma (ICD-O-3 8046/3) of the lung; primary biopsied or resected from the lung. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
